Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GE, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GE-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Melanoma back 0.9mm 1999 - mass L axilla. Radical L axillary dissection.

MACROSCOPIC DESCRIPTION

(Dr

"CONTENTS OF LEFT AXILLA". An irregular shaped piece of fatty tissue including skeletal muscle 120x110x25mm. There is a large palpable nodule 40mm in diameter in the centre of the specimen. The cut surface shows a soft fleshy appearance with areas of necrosis. There are multiple enlarged lymph nodes within the specimen and mostly surrounding the largest nodule. The largest nodule has been sampled for tumour banking at the fresh state.

- A. Representative sections of the largest nodule
- B. Three nodes
- C. One node
- D. One node
- E. Three nodes
- F. Three nodes

100-0-3

Melanoma, amelanotic 8730/3

Site: lymph node, axilla C77.3

lw 4/10/11

MICROSCOPIC REPORT

"CONTENTS OF LEFT AXILLA". The largest nodule (1A) is virtually replaced by metastatic amelanotic melanoma, with extracapsular spread. The remaining 11 lymph nodes show no evidence of malignancy.

SUMMARY

Lymph nodes left axilla - Metastatic melanoma (1/12).

REPORTED BY:

Source: NCI Genomic Data Commons file 182479c4-3bbb-41fe-a96a-ca59379bb6a4 (TCGA-EE-A2GE.AAD7F74E-A8D6-443A-A9F7-2ED1F7BF78EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).